Gene-level copy-number profile of tumor specimen ALCH-B3AP-TTP1-A from ALCHEMIST case ALCH-B3AP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 67.0 years (24,487 days).
Specimen ALCH-B3AP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 11be538c-8d26-433e-a9dc-7bd6f8e873d2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3AP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/0871ae66-8228-473f-80f2-57f4eaf39b9b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 99; copy number 1: 3,312; copy number 2: 51,560; copy number 3: 3,900; copy number 4: 13; copy number 5: 3; copy number 6: 1; copy number 18: 4; copy number 20: 5; copy number 24: 3; copy number 38: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:625,573–670,782, 3 genes: PDE6B, PDE6B-AS1, AC107464.2.
- chr8:42,484,600–42,485,019, 1 gene (within-gene range 0–2): AC093367.1.
- chr8:142,910,559–142,917,843, 1 gene (within-gene range 0–3): CYP11B2.
- chr16:2,682,523–2,709,030, 2 genes (within-gene range 0–2): KCTD5, AC092117.2.
- chr19:1,874,871–1,885,496, 3 genes: AC012615.1, AC012615.5, ABHD17A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:32,649,193–32,678,831, 5 genes, copy number 20: AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3.
- chr16:32,845,964–32,846,180, 1 gene, copy number 5: AC142086.2.
- chr16:90,102,271–90,178,344, 1 gene, copy number 18 (within-gene range 2–18): FAM157C.
- chr16:90,110,574–90,222,851, 4 genes, copy number 18–38: AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr18:45,034–46,047, 1 gene, copy number 5: AP001005.1.
- chr21:44,200,602–44,244,993, 4 genes, copy number 5–24: AP001057.1, ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 890. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
